Somatic mutation profile of tumor specimen 0E1FGQ from CCDI case PBCVPL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1FGQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63d01c94-6851-4187-a754-676bc3931142.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1FGU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afa651f1-5d30-46f3-805f-fc9cfd5972cf

The open-access MAF lists 44 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Nonsense Mutation 5, Intron 4, Frame Shift Del 2, 5'Flank 2, RNA 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 221/364 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 148/158 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CCNB3 | c.2795C>T p.A932V | Missense Mutation (SNP) | VAF 68/858 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1557214785, COSV52072898; called by muse, mutect2
- DNAI3 | c.2666A>G p.E889G | Missense Mutation (SNP) | VAF 104/334 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV54001941; called by muse, mutect2, varscan2
- IRX1 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 204/521 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.067); catalogued as rs774952040, COSV57358768; called by muse, mutect2, varscan2
- MUC16 | c.31162C>A p.P10388T | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs768804590, COSV101201973; called by muse, mutect2
- NOTCH3 | c.4807G>C p.D1603H | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV54636644, COSV99658734; called by muse, mutect2, varscan2
- SLC30A8 | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 118/548 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.363); catalogued as COSV101438135; called by muse, mutect2, varscan2
- TASOR | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 28/494 reads (6%) | catalogued as rs1167250399; called by muse, mutect2
- TBC1D1 | c.1435A>G p.N479D | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as COSV54721228; called by muse, mutect2
- TRPC3 | c.1049G>T p.C350F (on ENST00000379645 / NM_001366479.2; = p.C277F on NM_003305.2) | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs779107179, COSV53374671; called by muse, mutect2
- ADCK2 | c.32T>A p.V11D | Missense Mutation (SNP) | VAF 30/880 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2
- ANKRD30B | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 166/620 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- BRF1 | c.1995C>G p.N665K | Missense Mutation (SNP) | VAF 80/372 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.389); called by mutect2, varscan2
- CHKB | c.508A>T p.K170* | Nonsense Mutation (SNP) | VAF 18/553 reads (3%) | called by muse, mutect2
- COMP | c.2117del p.V706Gfs*? | Frame Shift Del (DEL) | VAF 109/358 reads (30%) | called by mutect2, pindel, varscan2
- FSIP2 | c.12880A>T p.R4294* | Nonsense Mutation (SNP) | VAF 37/628 reads (6%) | called by muse, mutect2
- LAMTOR1 | c.343_362del p.P115* | Frame Shift Del (DEL) | VAF 63/378 reads (17%) | called by mutect2, pindel, varscan2
- MGAM | c.59T>A p.L20Q | Missense Mutation (SNP) | VAF 42/514 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- NOVA1 | c.217G>T p.V73F | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- PAX3 | c.1287C>A p.C429* | Nonsense Mutation (SNP) | VAF 88/330 reads (27%) | called by muse, mutect2, varscan2
- PQBP1 | c.642-5G>A | Splice Region (SNP) | VAF 94/438 reads (21%) | called by muse, mutect2, varscan2
- RPS6KA5 | c.1649T>A p.L550* | Nonsense Mutation (SNP) | VAF 34/167 reads (20%) | called by muse, mutect2, varscan2
- RTL5 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 26/848 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- TCERG1L | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 49/695 reads (7%) | SIFT tolerated, low confidence (0.73); PolyPhen possibly damaging (0.794); called by muse, mutect2
- TRPM6 | c.4621A>C p.S1541R | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- VWDE | c.1939G>C p.A647P | Missense Mutation (SNP) | VAF 168/266 reads (63%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP5 | c.3636G>A p.T1212= | Silent (SNP) | VAF 157/402 reads (39%) | catalogued as rs767758345, COSV70493671; called by muse, mutect2, varscan2
- FAM47B | c.1077C>T p.D359= | Silent (SNP) | VAF 151/852 reads (18%) | catalogued as rs770049861, COSV61453958; called by muse, mutect2, varscan2
- H2AC14 | c.66C>G p.A22= | Silent (SNP) | VAF 79/375 reads (21%) | catalogued as rs201651725, COSV60797836; called by muse, mutect2, varscan2
- LTBP2 | c.471C>A p.T157= | Silent (SNP) | VAF 41/382 reads (11%) | called by muse, mutect2, varscan2
- MYO1E | c.1164C>T p.D388= | Silent (SNP) | VAF 33/336 reads (10%) | catalogued as rs1566981210; called by muse, mutect2, varscan2
- OR2W3 | c.108C>G p.L36= | Silent (SNP) | VAF 28/412 reads (7%) | catalogued as COSV64457348; called by muse, mutect2
- PYGO2 | c.1149C>G p.L383= | Silent (SNP) | VAF 67/450 reads (15%) | catalogued as COSV63756635; called by muse, mutect2, varscan2
- TEX13A | c.210C>A p.G70= | Silent (SNP) | VAF 72/820 reads (9%) | called by muse, mutect2
- TP53 | c.726C>T p.C242= | Silent (SNP) | VAF 150/159 reads (94%) | catalogued as rs375874539, CM102354, COSV52677195, COSV52704436, COSV53034631; called by muse, mutect2, varscan2
- C9orf62 | n.576G>T | RNA (SNP) | VAF 110/188 reads (59%) | called by muse, mutect2, varscan2
- CCDC154 | c.1180-40C>T | Intron (SNP) | VAF 56/124 reads (45%) | catalogued as rs1395628923; called by muse, mutect2, varscan2
- CHCHD7 | c.153+29A>G | Intron (SNP) | VAF 44/282 reads (16%) | called by muse, mutect2, varscan2
- CNKSR2 | c.1905-53G>T | Intron (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- CST4 | c.-47C>A | 5'UTR (SNP) | VAF 41/166 reads (25%) | called by muse, mutect2, varscan2
- ENOSF1 | c.680-18G>A | Intron (SNP) | VAF 50/163 reads (31%) | catalogued as rs753824568; called by muse, mutect2, varscan2
- PTOV1 | chr19:49850941 C>T | 5'Flank (SNP) | VAF 31/225 reads (14%) | called by muse, mutect2, varscan2
- TIAM1 | chr21:31559373 C>A | 5'Flank (SNP) | VAF 82/194 reads (42%) | called by muse, mutect2, varscan2
